TCGA case TCGA-04-1350 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f4a4ad1-e394-45c4-9aa9-aadf2bff0628

Demographics
Sex at birth: female; Race: white; Age at index: 46 years; Vital status: Dead; Days to death: 1,946 days (5.3 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 46.4 years (16,942 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 216 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 363 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 720 days (2.0 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,389 days (3.8 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 1,389 days (3.8 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 1,580 days (4.3 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Exemestane; Initial disease status: Progressive Disease; Days to treatment start: 1,622 days (4.4 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Fulvestrant; Initial disease status: Progressive Disease; Days to treatment start: 1,726 days (4.7 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 46.7 years (17,053 days); Days to diagnosis: 111 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 111 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 111 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,946 days (5.3 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1350-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-04-1350-01A-01-TS1: Section location: Top; Percent tumor cells: 94; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 5.
  Slide TCGA-04-1350-01A-01-BS1: Section location: Bottom; Percent tumor cells: 94; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 5.
- Sample TCGA-04-1350-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1.4; Shortest dimension: 0.1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 2: Pharmaceutical therapy drug name: Gemcitibine; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Fuluestrant; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Aromasin; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Faslodex; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Stable Disease; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,946 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,946 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 111 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-04-1350-01): tumor purity 0.99, ploidy 3.04, whole-genome doublings 1 (call status: legacy_call).
